Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5752, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5752-01A (Primary Tumor).

Diagnosis

1. Poorly differentiated, max. 2.8 cm adenocarcinoma of the prostate in both lobes with marked perineural growth along major nerves, infiltration of the periprostatic connective tissue in the region of the right middle section of the prostate and the right base of the prostate, as well as invasion of the vessels. Tumor-free seminal vesicles and seminal ducts.
2. Six tumor-free lymph nodes.
3. Three tumor-free lymph nodes.

Remark

Carcinoma infiltrates are found in the peripheral and transitional zone of both sides with right-sided predominance. Carcinoma cells extend to several points (right lateral apex, right medial apex, left medial apex) < 0.1 mm on the green and blue labeled preparation margin. The color labeling itself is tumor-free. Small foci of carcinoma differentiated as Gleason 3 are seen as a tertiary Gleason score.

Summarizing tumor classification: pT3a, pN0 (0/9), Gleason 4+4 = 8; G3, L1, V0.

A follow-up report will follow on the question of a possible neuroendocrine differentiation.

Source: NCI Genomic Data Commons file fb1f3571-5e6c-400d-8e59-868b749483b5 (TCGA-CH-5752.D3549715-B952-479C-8EDF-86E424811095.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).